Gene-level copy-number profile of tumor specimen TCGA-DY-A1DF-01A from TCGA case TCGA-DY-A1DF, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 73.3 years (26,763 days).
Specimen TCGA-DY-A1DF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.c50f7973-32fc-4ad8-9c04-9edd72c7c94d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DY-A1DF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/04c7af3c-c6b8-4de6-9dbf-a73dc9664f76

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 500; copy number 2: 18,713; copy number 3: 19,151; copy number 4: 15,313; copy number 5: 1,990; copy number 6: 2,736; copy number 8: 23; copy number 10: 98; copy number 11: 1,139; copy number 12: 96; copy number 13: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DY-A1DF-01A-11D-A151-01): tumor purity 0.92, ploidy 3.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,406 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–54,142,319, 719 genes, copy number 10–12 (broad region; genes not listed).
- chr13:55,535,697–114,337,626, 664 genes, copy number 11–13 (broad region; genes not listed).
- chr18:14,728,272–15,330,282, 23 genes, copy number 8 (within-gene range 3–8): ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.

Autosomal genes at a single copy (total copy number 1): 500. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
